Somatic mutation profile of tumor specimen TCGA-FD-A6TB-01A (aliquot TCGA-FD-A6TB-01A-12D-A339-08) from TCGA case TCGA-FD-A6TB, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 82.6 years (30,185 days).
Specimen TCGA-FD-A6TB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8fe1aeec-25ea-4f4d-a878-99ea754c4fd1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A6TB-10A (Blood Derived Normal), aliquot TCGA-FD-A6TB-10A-21D-A339-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b2ca9fd-e470-4aa4-8661-33e9e3b592c8

The open-access MAF lists 213 somatic variants for this specimen: 161 protein-altering or splice-affecting, 47 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 138, Silent 47, Nonsense Mutation 17, Splice Site 3, RNA 2, 3'Flank 2, Splice Region 1, In Frame Del 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.6610C>T p.R2204* | Nonsense Mutation (SNP) | VAF 18/123 reads (15%) | catalogued as rs752654519, COSV57326468, COSV99965912; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TSC1 | c.2507C>G p.S836* | Nonsense Mutation (SNP) | VAF 21/93 reads (23%) | catalogued as rs118203706, CM971525, COSV53773308; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA12 | c.5202C>G p.I1734M (on ENST00000272895 / NM_173076.3; = p.I1416M on NM_015657.3) | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as rs1232994666, COSV55973927; called by muse, mutect2, varscan2
- ACTB | c.842C>G p.S281C | Missense Mutation (SNP) | VAF 35/288 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV59321059; called by muse, mutect2, varscan2
- AEBP1 | c.2491C>T p.R831C | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56260987; called by muse, mutect2, varscan2
- AKAP9 | c.11013C>G p.I3671M (on ENST00000359028; = p.I3647M on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); catalogued as COSV62356920; called by muse, mutect2, varscan2
- ARID2 | c.1691C>T p.S564L | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57603916; called by muse, mutect2, varscan2
- ASH1L | c.5173G>A p.E1725K | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as COSV64213175; called by muse, mutect2, varscan2
- ASTN1 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.187); catalogued as rs370485432; called by muse, mutect2, varscan2
- BCAS2 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.141); catalogued as COSV65767793; called by muse, varscan2
- BCAS2 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.791); catalogued as COSV65767798; called by muse, varscan2
- BTG4 | c.469C>A p.R157S | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.056); catalogued as COSV63635294, COSV63636855; called by muse, mutect2, varscan2
- C1orf194 | c.308C>A p.T103N (on ENST00000369948 / NM_001245025.3; = p.T91N on NM_001122961.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.329); catalogued as COSV64050158; called by mutect2, varscan2
- C3orf70 | c.414T>A p.C138* | Nonsense Mutation (SNP) | VAF 16/125 reads (13%) | catalogued as COSV100621298; called by muse, mutect2, varscan2
- CAPN1 | c.1905G>C p.M635I | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.222); catalogued as COSV54201320; called by muse, mutect2, varscan2
- CCDC114 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as COSV59558548; called by muse, mutect2, varscan2
- CCDC185 | c.1539G>C p.K513N | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64821798; called by muse, mutect2, varscan2
- CD82 | c.60C>G p.F20L | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); catalogued as COSV57037251; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1657G>C p.E553Q (on ENST00000357886 / NM_001365728.1; = p.E539Q on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.14); catalogued as rs1299048326, COSV59428791; called by muse, mutect2
- CENPL | c.524C>T p.S175L | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs566411021, COSV61892940; called by muse, mutect2, varscan2
- CIP2A | c.819-1G>A p.X273_splice | Splice Site (SNP) | VAF 13/120 reads (11%) | catalogued as COSV55421155; called by muse, mutect2, varscan2
- CLEC14A | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60564115; called by muse, mutect2, varscan2
- COG5 | c.1282G>C p.D428H | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV51763158; called by muse, mutect2, varscan2
- COL14A1 | c.1151G>A p.R384K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.621); catalogued as COSV52866929; called by muse, mutect2, varscan2
- CSE1L | c.417G>C p.Q139H | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.235); catalogued as COSV53704924; called by muse, mutect2, varscan2
- DAPK1 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.27); catalogued as COSV63791653; called by muse, mutect2, varscan2
- DDX59 | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58753955; called by muse, mutect2, varscan2
- DLD | c.1290G>C p.K430N | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52739604; called by muse, mutect2, varscan2
- DLG1 | c.1933C>T p.R645C | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1370279637, COSV58390597; called by muse, mutect2, varscan2
- DNAJC9 | c.551A>G p.Q184R | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as COSV54354435; called by muse, mutect2, varscan2
- DOT1L | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 95/702 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV67113041; called by muse, mutect2, varscan2
- DRGX | c.752C>G p.S251C | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.219); catalogued as COSV100938344, COSV65137504; called by muse, mutect2
- EDRF1 | c.3537G>C p.K1179N (on ENST00000356792 / NM_001202438.2; = p.K1145N on NM_015608.2) | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.146); catalogued as rs1392246290, COSV61766103; called by muse, mutect2
- EEF1AKNMT | c.1358C>T p.A453V (on ENST00000361735 / NM_015935.5; = p.A367V on NM_014955.3) | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs752973393, COSV62283080; called by muse, mutect2, varscan2
- ELF3 | c.708G>C p.K236N | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.307); catalogued as COSV62838469, COSV62839686; called by muse, mutect2, varscan2
- EPHB3 | c.1864C>T p.R622W | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1268552150, COSV57807885; called by muse, mutect2
- EPS8L2 | c.1097C>G p.S366C | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59349498, COSV59350074; called by muse, mutect2, varscan2
- EPS8L2 | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV59348097; called by muse, mutect2, varscan2
- ERBB2 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); catalogued as rs1241783659, COSV54081804; called by muse, mutect2, varscan2
- ERBB3 | c.2773G>C p.E925Q | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57246944, COSV57256094; called by muse, mutect2, varscan2
- EXPH5 | c.416C>G p.S139* | Nonsense Mutation (SNP) | VAF 24/192 reads (13%) | catalogued as COSV99761936; called by muse, varscan2
- EZR | c.586C>A p.Q196K | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61455942; called by muse, mutect2
- EZR | c.549C>T p.L183= | Splice Region (SNP) | VAF 8/62 reads (13%) | catalogued as rs1360263899, COSV61455948; called by muse, mutect2
- FAAP100 | c.2535G>C p.Q845H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100585488; called by muse, mutect2
- FASTKD1 | c.2282C>G p.S761* | Nonsense Mutation (SNP) | VAF 7/65 reads (11%) | catalogued as COSV101494300; called by muse, mutect2, varscan2
- FBXO11 | c.679G>A p.E227K (on ENST00000403359 / NM_001190274.2; = p.E143K on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV57017372; called by muse, mutect2, varscan2
- FLG2 | c.3374C>G p.S1125C | Missense Mutation (SNP) | VAF 71/559 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.887); catalogued as rs112104081, COSV66167411, COSV66172723; called by muse, mutect2, varscan2
- FLT1 | c.2422G>A p.E808K | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV56741547, COSV56747888; called by muse, mutect2
- GATA2 | c.1234G>C p.E412Q | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.391); catalogued as COSV62006792; called by muse, mutect2, varscan2
- GBP4 | c.1313G>C p.R438T | Missense Mutation (SNP) | VAF 38/482 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as rs1266378531, COSV63255861; called by muse, mutect2
- GBP4 | c.1236G>C p.Q412H | Missense Mutation (SNP) | VAF 35/374 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV63255865; called by muse, mutect2
- GNA13 | c.599G>C p.R200T | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV71474364, COSV71474492; called by muse, mutect2, varscan2
- GNAI2 | c.1035C>G p.I345M | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.798); catalogued as COSV56495642; called by muse, mutect2
- GOLIM4 | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV58331834; called by muse, mutect2, varscan2
- GPRASP1 | c.2995G>A p.E999K | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64356399; called by muse, mutect2, varscan2
- H4C4 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as rs773088974, COSV61590715; called by muse, mutect2
- HIKESHI | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.378); catalogued as COSV53575698; called by muse, mutect2, varscan2
- HNRNPDL | c.860T>A p.V287E | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55023453; called by muse, mutect2
- HOOK3 | c.148C>G p.P50A | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV56881664, COSV56887352; called by muse, varscan2
- INTS9 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1205279074, COSV68435486, COSV68435751; called by muse, mutect2, varscan2
- IRS1 | c.3067G>A p.E1023K | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1171711422, COSV59338026, COSV59339732; called by muse, mutect2, varscan2
- ITGB4 | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 61/318 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.725); catalogued as COSV52325770, COSV52332086; called by muse, mutect2, varscan2
- JAK2 | c.899G>A p.R300K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67668827; called by muse, mutect2, varscan2
- KCNH3 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57789511; called by muse, mutect2
- KCNS1 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60261001; called by muse, mutect2
- KIF16B | c.3637G>A p.E1213K | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs772299075, COSV100734650, COSV61713933; called by muse, mutect2, varscan2
- KLB | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV57303036, COSV57304910; called by muse, mutect2, varscan2
- KLF10 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as COSV53436727; called by muse, mutect2, varscan2
- KRT5 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 32/281 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52863208; called by muse, mutect2, varscan2
- LAMA2 | c.475G>C p.D159H | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70354512; called by muse, mutect2, varscan2
- LRP5 | c.4005C>G p.I1335M | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.77); catalogued as COSV53713540, COSV53723168; called by muse, mutect2, varscan2
- MAB21L3 | c.109C>A p.H37N | Missense Mutation (SNP) | VAF 34/277 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV65674481; called by muse, mutect2, varscan2
- MAEL | c.736G>C p.E246Q | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100774771, COSV63112637; called by muse, mutect2, varscan2
- MARK1 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV65070994; called by muse, mutect2, varscan2
- MAS1L | c.591C>G p.I197M | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV65809635, COSV65809641; called by muse, mutect2, varscan2
- MCCC1 | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99659945; called by muse, varscan2
- METTL3 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 12/77 reads (16%) | catalogued as COSV99398457; called by muse, mutect2, varscan2
- MGA | c.5822C>G p.S1941C (on ENST00000219905 / NM_001164273.1; = p.S1732C on NM_001080541.2) | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54957143, COSV54962154; called by muse, mutect2, varscan2
- MGA | c.6319C>G p.Q2107E (on ENST00000219905 / NM_001164273.1; = p.Q1898E on NM_001080541.2) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as COSV54962162; called by muse, mutect2, varscan2
- MLC1 | c.792A>G p.I264M | Missense Mutation (SNP) | VAF 33/230 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.509); catalogued as COSV61118706; called by muse, mutect2, varscan2
- MTRF1 | c.106G>C p.D36H | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.146); catalogued as COSV53482173; called by muse, mutect2, varscan2
- MUC16 | c.33133C>G p.L11045V | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.603); catalogued as COSV101201997, COSV67490431; called by muse, mutect2, varscan2
- MUC16 | c.28815C>A p.Y9605* | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | catalogued as rs770623653, COSV101200545; called by muse, mutect2, varscan2
- MUC16 | c.4471C>T p.P1491S | Missense Mutation (SNP) | VAF 39/277 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1286814791, COSV67468195; called by muse, mutect2, varscan2
- MX2 | c.78G>A p.M26I | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV58099245; called by muse, mutect2
- MYH9 | c.2296G>A p.G766S | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs757850500, COSV53392219; called by muse, mutect2, varscan2
- MYH9 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV53392598; called by muse, mutect2, varscan2
- NAB1 | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV61609389; called by muse, mutect2, varscan2
- NAB1 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV61609273; called by muse, mutect2, varscan2
- NAPG | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 13/104 reads (13%) | catalogued as COSV100529872; called by muse, mutect2, varscan2
- NAV2 | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 21/91 reads (23%) | catalogued as COSV100586745, COSV62319587; called by muse, mutect2, varscan2
- NCOR1 | c.4764G>C p.Q1588H | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); catalogued as COSV51994459; called by muse, mutect2, varscan2
- NECTIN1 | c.1477G>C p.E493Q | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as COSV50607385; called by mutect2, varscan2
- NEK10 | c.3044C>G p.S1015* | Nonsense Mutation (SNP) | VAF 18/96 reads (19%) | catalogued as COSV99835446; called by mutect2, varscan2
- NEURL4 | c.2111C>T p.S704F | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as rs1183292551, COSV59753111; called by muse, mutect2, varscan2
- NTNG2 | c.1223-1G>A p.X408_splice | Splice Site (SNP) | VAF 3/50 reads (6%) | catalogued as COSV62367991; called by muse, mutect2
- NTRK1 | c.2299G>A p.E767K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV100693601; called by muse, mutect2
- NUTM1 | c.2542G>A p.D848N | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs764240832, COSV59218801; called by muse, mutect2, varscan2
- OR2AK2 | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 67/469 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV63560258; called by muse, mutect2, varscan2
- PALD1 | c.1840C>T p.R614C | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs756962803, COSV54978464; called by muse, mutect2, varscan2
- PAXBP1 | c.2686G>C p.D896H | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV59508550; called by muse, mutect2, varscan2
- PCDHB5 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50653874; called by muse, mutect2
- PDCL | c.874C>T p.H292Y | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52343478; called by muse, mutect2, varscan2
- PDCL | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 14/90 reads (16%) | catalogued as COSV99414087, COSV99414171; called by muse, mutect2, varscan2
- PHACTR3 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs149282803; called by muse, mutect2
- PHLDB2 | c.3036G>T p.M1012I (on ENST00000393925 / NM_001134439.2; = p.M969I on NM_145753.2) | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as COSV67315650; called by muse, mutect2, varscan2
- PLA2G4C | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 32/235 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV62784390; called by muse, mutect2, varscan2
- PNMA8B | c.1520C>T p.S507L | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.092); catalogued as rs545570021, COSV100885481; called by muse, mutect2, varscan2
- POLD3 | c.964A>G p.R322G | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as COSV55245642; called by muse, mutect2, varscan2
- PPP2R5D | c.357C>G p.I119M | Missense Mutation (SNP) | VAF 27/314 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.212); catalogued as COSV57841353; called by muse, mutect2
- PPP2R5D | c.1669C>T p.Q557* | Nonsense Mutation (SNP) | VAF 8/150 reads (5%) | catalogued as COSV99775819; called by muse, mutect2
- PRKAR2A | c.1040G>C p.R347T | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55554164; called by muse, mutect2, varscan2
- PRRC2C | c.2599G>C p.E867Q (on ENST00000367742; = p.E865Q on NM_015172.4) | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV58912293; called by muse, mutect2, varscan2
- PTER | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV54347314; called by muse, mutect2, varscan2
- PTPN22 | c.873G>C p.K291N | Missense Mutation (SNP) | VAF 37/272 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV63086456; called by muse, mutect2, varscan2
- RBM14 | c.1277C>G p.S426C | Missense Mutation (SNP) | VAF 47/352 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59560554; called by muse, mutect2, varscan2
- RBM4 | c.869_886del p.A290_A295del | In Frame Del (DEL) | VAF 19/157 reads (12%) | catalogued as rs759186690; called by mutect2, pindel, varscan2
- REG1B | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.074); catalogued as COSV59307665; called by muse, mutect2, varscan2
- RHOB | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV55357168; called by muse, mutect2, varscan2
- RHOB | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55357180; called by muse, mutect2
- RHOB | c.463G>C p.D155H | Missense Mutation (SNP) | VAF 36/254 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV55357194; called by muse, varscan2
- RHOB | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV55355253; called by muse, varscan2
- RPS2 | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as rs1217398563, COSV99238886; called by muse, mutect2
- RTP3 | c.372G>C p.K124N | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56124378; called by muse, mutect2
- SEPTIN11 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53584504; called by muse, mutect2, varscan2
- SH2B3 | c.1298C>T p.S433L | Missense Mutation (SNP) | VAF 15/244 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780842512, COSV57986402; called by muse, mutect2
- SLAMF7 | c.833C>G p.S278C | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as rs1291325288, COSV100833209, COSV63564029; called by muse, mutect2, varscan2
- SLC17A8 | c.1426-1G>C p.X476_splice | Splice Site (SNP) | VAF 9/73 reads (12%) | catalogued as COSV60126437; called by muse, mutect2, varscan2
- SLC24A4 | c.1682C>T p.S561F | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1472393642, COSV54108219; called by muse, mutect2
- SLC6A4 | c.1330G>C p.E444Q | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55569426; called by muse, mutect2, varscan2
- SLC6A9 | c.1300G>T p.D434Y (on ENST00000360584 / NM_201649.4; = p.D380Y on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62212016; called by muse, mutect2, varscan2
- SMG1 | c.6947C>G p.S2316C | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV101246556; called by muse, mutect2
- SNED1 | c.2005G>A p.G669R | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV60032769; called by muse, mutect2, varscan2
- SPEN | c.9008C>T p.S3003L | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1386910185, COSV65358324; called by muse, mutect2, varscan2
- SRRM2 | c.7004C>G p.S2335C | Missense Mutation (SNP) | VAF 67/529 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.219); catalogued as rs140636308, COSV51941795; called by muse, mutect2, varscan2
- SRRM2 | c.7535C>G p.S2512C | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV51941797; called by muse, mutect2, varscan2
- STK32A | c.528G>T p.Q176H | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.353); catalogued as COSV60422724; called by muse, mutect2, varscan2
- STK38L | c.293G>C p.R98T | Missense Mutation (SNP) | VAF 32/252 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV66523028; called by muse, mutect2, varscan2
- STXBP4 | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as COSV54843671; called by muse, varscan2
- STXBP5L | c.708G>C p.W236C | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56533045; called by muse, mutect2
- TAF1D | c.255G>C p.K85N | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100127110, COSV58679456, COSV58682105; called by muse, mutect2, varscan2
- TCN1 | c.995C>G p.S332* | Nonsense Mutation (SNP) | VAF 15/122 reads (12%) | catalogued as COSV57252822, COSV99953366; called by muse, mutect2, varscan2
- TCOF1 | c.2635G>A p.E879K (on ENST00000377797 / NM_001135243.1; = p.E802K on NM_000356.4) | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); catalogued as rs1405440628, COSV60353763; called by muse, mutect2, varscan2
- TDRD6 | c.5079G>C p.E1693D | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV60178299; called by muse, mutect2
- TEKT1 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 22/97 reads (23%) | catalogued as rs143066578, COSV58622407, COSV58622706; called by muse, mutect2, varscan2
- TIE1 | c.3406G>A p.E1136K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65251233; called by muse, mutect2, varscan2
- TOGARAM1 | c.3248C>G p.S1083* | Nonsense Mutation (SNP) | VAF 13/109 reads (12%) | catalogued as COSV100818180, COSV63893074; called by muse, mutect2, varscan2
- TTN | c.59647C>G p.L19883V (on ENST00000591111; = p.L12459V on NM_003319.4) | Missense Mutation (SNP) | VAF 17/371 reads (5%) | PolyPhen benign (0.341); catalogued as rs1378663120, COSV60313473; called by muse, mutect2
- UGT2B17 | c.508C>G p.L170V | Missense Mutation (SNP) | VAF 22/448 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58501487; called by muse, mutect2
- USF3 | c.6377C>G p.S2126* | Nonsense Mutation (SNP) | VAF 20/168 reads (12%) | catalogued as COSV100325578; called by muse, mutect2, varscan2
- UVSSA | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs371967224, COSV66229694; called by muse, mutect2, varscan2
- XIRP1 | c.2986C>G p.Q996E | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV61140821; called by muse, mutect2, varscan2
- ZBTB20 | c.2151C>G p.C717W (on ENST00000474710 / NM_001164342.2; = p.C644W on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100615537, COSV61866832; called by muse, mutect2, varscan2
- ZBTB22 | c.1853C>G p.P618R | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs147609143; called by muse, mutect2, varscan2
- ZBTB47 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.039); catalogued as COSV51765727; called by muse, mutect2, varscan2
- ZBTB47 | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV51765737; called by muse, mutect2, varscan2
- ZFP36L2 | c.718G>C p.D240H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as COSV56697423, COSV56700013; called by muse, mutect2, varscan2
- ZNF283 | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.03); catalogued as COSV100191062, COSV61032614; called by muse, mutect2, varscan2
- ZNF429 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV61918791; called by muse, mutect2, varscan2
- GGNBP2 | c.1207C>T p.Q403* | Nonsense Mutation (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2, varscan2
- KANSL1 | c.703_707del p.N235Hfs*11 | Frame Shift Del (DEL) | VAF 20/150 reads (13%) | called by mutect2, pindel, varscan2
- ARHGEF16 | c.1299G>A p.L433= | Silent (SNP) | VAF 24/119 reads (20%) | catalogued as COSV65683204; called by muse, mutect2, varscan2
- ARMC6 | c.1464C>G p.L488= (on ENST00000392336; = p.L463= on NM_033415.4) | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV54183999; called by mutect2, varscan2
- BDH1 | c.522G>A p.R174= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as rs1311766923, COSV64019704; called by muse, mutect2, varscan2
- BRD4 | c.3753G>A p.E1251= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV54594295; called by muse, mutect2, varscan2
- CDH13 | c.1566T>C p.G522= | Silent (SNP) | VAF 36/274 reads (13%) | catalogued as COSV51864755; called by muse, mutect2, varscan2
- CES3 | c.648C>T p.F216= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs768694829, COSV57592693; called by muse, mutect2, varscan2
- CNNM4 | c.1062C>T p.L354= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as rs929526785, COSV65660218; called by muse, mutect2, varscan2
- COX11 | c.231G>C p.S77= | Silent (SNP) | VAF 18/171 reads (11%) | catalogued as COSV54803818; called by muse, mutect2, varscan2
- CTNND2 | c.1848G>A p.L616= | Silent (SNP) | VAF 27/223 reads (12%) | catalogued as COSV58889941; called by muse, mutect2, varscan2
- EEF1A2 | c.39C>T p.I13= | Silent (SNP) | VAF 23/231 reads (10%) | catalogued as rs762508675, COSV53206903; called by muse, mutect2, varscan2
- ERBB2 | c.657C>A p.V219= | Silent (SNP) | VAF 27/205 reads (13%) | catalogued as COSV54081824; called by muse, varscan2
- FAT4 | c.1152C>T p.D384= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV67888072; called by muse, mutect2, varscan2
- FGR | c.387C>T p.P129= | Silent (SNP) | VAF 7/95 reads (7%) | catalogued as COSV64969772; called by muse, mutect2
- GLB1L2 | c.1545G>A p.L515= | Silent (SNP) | VAF 35/339 reads (10%) | catalogued as COSV57000454; called by muse, mutect2, varscan2
- HTRA2 | c.576C>G p.L192= | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as COSV51213270; called by muse, mutect2, varscan2
- KHNYN | c.1914C>G p.L638= | Silent (SNP) | VAF 18/184 reads (10%) | catalogued as COSV52163268; called by muse, mutect2
- KMT2A | c.7281G>A p.Q2427= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV63292108; called by muse, mutect2, varscan2
- LSM12 | c.327C>T p.V109= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV99518610; called by muse, mutect2, varscan2
- MGAM | c.4281C>T p.F1427= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV72074588; called by muse, mutect2, varscan2
- MICAL1 | c.1119G>A p.E373= | Silent (SNP) | VAF 11/153 reads (7%) | catalogued as COSV62196032; called by muse, mutect2
- MMP24 | c.588G>A p.Q196= | Silent (SNP) | VAF 154/465 reads (33%) | catalogued as COSV55772933; called by muse, mutect2, varscan2
- MOB3B | c.208C>A p.R70= | Silent (SNP) | VAF 26/170 reads (15%) | catalogued as COSV51781953, COSV51789412; called by muse, mutect2, varscan2
- MUC15 | c.60G>A p.G20= | Silent (SNP) | VAF 12/147 reads (8%) | catalogued as COSV55556938; called by muse, mutect2
- NAPSA | c.132G>A p.L44= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as COSV53798994; called by muse, mutect2, varscan2
- NCKAP1 | c.1911C>T p.I637= | Silent (SNP) | VAF 26/145 reads (18%) | catalogued as COSV62943324; called by muse, mutect2, varscan2
- OCRL | c.792T>C p.C264= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV63981815; called by muse, mutect2, varscan2
- OTOP2 | c.174C>T p.Y58= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs777873109, COSV58883586; called by muse, mutect2, varscan2
- PCDHB8 | c.1860G>A p.A620= | Silent (SNP) | VAF 30/250 reads (12%) | called by muse, varscan2
- PDCL | c.546C>T p.V182= | Silent (SNP) | VAF 23/159 reads (14%) | catalogued as rs759211052, COSV52343489; called by muse, mutect2, varscan2
- PHKA2 | c.2046G>A p.K682= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV66056020; called by muse, mutect2, varscan2
- PPP1R14B | c.381C>T p.F127= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as COSV58588532; called by muse, mutect2, varscan2
- PPP2R5D | c.774C>T p.L258= | Silent (SNP) | VAF 24/222 reads (11%) | catalogued as rs1277483823, COSV55151491, COSV99776545; called by muse, mutect2, varscan2
- PPP5C | c.1200G>C p.R400= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as COSV50143457; called by muse, mutect2
- PSD2 | c.2157C>T p.I719= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV51209385; called by muse, mutect2, varscan2
- RADIL | c.1722C>T p.V574= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as COSV68203385; called by muse, mutect2, varscan2
- RECQL4 | c.3447G>A p.L1149= | Silent (SNP) | VAF 28/184 reads (15%) | catalogued as COSV56740300, COSV56743001; called by muse, varscan2
- SHPRH | c.4557G>C p.L1519= (on ENST00000275233 / NM_001042683.3; = p.L1523= on NM_173082.3) | Silent (SNP) | VAF 40/268 reads (15%) | catalogued as COSV51616949; called by muse, mutect2, varscan2
- SLC2A1 | c.765G>A p.K255= | Silent (SNP) | VAF 14/190 reads (7%) | catalogued as COSV65288364; called by muse, mutect2
- SLC35E3 | c.153C>T p.F51= | Silent (SNP) | VAF 24/373 reads (6%) | catalogued as rs777415333, COSV57492674; called by muse, mutect2
- SSUH2 | c.250C>T p.L84= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV58033245; called by muse, mutect2, varscan2
- TMEM175 | c.111C>T p.L37= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as rs1039436927, COSV53281076; called by muse, varscan2
- TRIM42 | c.642C>A p.L214= | Silent (SNP) | VAF 23/195 reads (12%) | catalogued as COSV53882907, COSV53886632; called by muse, mutect2, varscan2
- TSC2 | c.3153C>T p.L1051= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as rs1298892692, COSV54765365; called by muse, mutect2
- XIRP2 | c.5019C>T p.L1673= (on ENST00000628543; = p.L1848= on NM_152381.6) | Silent (SNP) | VAF 21/155 reads (14%) | catalogued as rs1285507593, COSV54680506, COSV54731374; called by muse, mutect2, varscan2
- ZNF333 | c.12C>T p.V4= | Silent (SNP) | VAF 30/157 reads (19%) | catalogued as COSV52888268; called by muse, mutect2, varscan2
- ZNF524 | c.138C>G p.L46= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs769984023, COSV99684678; called by muse, mutect2
- ZZEF1 | c.7581G>A p.L2527= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV67560045; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152445670 G>C | 3'Flank (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2
- HCG27 | n.381G>C | RNA (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- MSI2 | c.63-34C>T | Intron (SNP) | VAF 8/80 reads (10%) | catalogued as COSV52367252; called by muse, mutect2
- PDLIM2 | chr8:22594616 G>A | 3'Flank (SNP) | VAF 15/115 reads (13%) | catalogued as COSV56134982; called by muse, mutect2, varscan2
- SSPOP | n.1874C>A | RNA (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100022758; called by muse, mutect2, varscan2
